Somatic mutation profile of tumor specimen TCGA-UY-A9PH-01A (aliquot TCGA-UY-A9PH-01A-11D-A38G-08) from TCGA case TCGA-UY-A9PH, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 73.0 years (26,654 days).
Specimen TCGA-UY-A9PH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a506e820-9e20-496a-ae79-1f672eb07729.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UY-A9PH-10A (Blood Derived Normal), aliquot TCGA-UY-A9PH-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a3bf2f3-6c18-4ebc-929d-c8acea403796

The open-access MAF lists 423 somatic variants for this specimen: 295 protein-altering or splice-affecting, 119 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 251, Silent 119, Nonsense Mutation 32, Splice Site 5, Splice Region 3, Intron 2, RNA 2, 3'UTR 2, Translation Start Site 2, 5'UTR 2, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNNM2 | c.806C>G p.S269W | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs794726858, CM144644, COSV63996518; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 21/51 reads (41%) | hotspot (GDC flag); catalogued as CM1511153, COSV52664188; called by muse, mutect2, varscan2
- TYMP | c.162C>G p.I54M | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064792858, CM030063, COSV52689618; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS10 | c.667G>T p.E223* | Nonsense Mutation (SNP) | VAF 14/68 reads (21%) | catalogued as COSV99546968; called by muse, varscan2
- ADCK5 | c.1050G>C p.Q350H | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58235858; called by muse, mutect2, varscan2
- ADCY5 | c.3444C>G p.I1148M | Missense Mutation (SNP) | VAF 64/136 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.721); catalogued as COSV59205376; called by muse, mutect2, varscan2
- ADGRG3 | c.1448C>G p.S483W | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as rs200130702, COSV59652932; called by muse, mutect2, varscan2
- AHR | c.811C>G p.P271A | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as COSV54123588; called by muse, mutect2, varscan2
- AKAP13 | c.7495G>A p.D2499N (on ENST00000394518 / NM_007200.5; = p.D2503N on NM_006738.6) | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV63471324; called by muse, mutect2, varscan2
- AKAP9 | c.10165G>T p.E3389* (on ENST00000359028; = p.E3365* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as COSV100662437, COSV62346073, COSV62350356; called by muse, mutect2, varscan2
- AMIGO2 | c.692T>C p.V231A | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as COSV56975771; called by muse, mutect2, varscan2
- ANGPTL3 | c.980C>G p.S327C | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV52023473; called by muse, mutect2, varscan2
- ANKIB1 | c.676G>T p.E226* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as rs1301954713, COSV99729139; called by muse, mutect2
- ANKRD27 | c.289G>C p.E97Q | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV60136736; called by muse, mutect2, varscan2
- ANKRD30A | c.1705G>A p.E569K (on ENST00000611781; = p.E513K on NM_052997.2) | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.332); catalogued as COSV64623005; called by muse, mutect2, varscan2
- AOC1 | c.1477G>T p.E493* | Nonsense Mutation (SNP) | VAF 12/105 reads (11%) | catalogued as COSV100710787; called by muse, mutect2, varscan2
- APPL1 | c.630C>G p.F210L | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.852); catalogued as COSV55703950; called by muse, mutect2, varscan2
- AQR | c.1263G>T p.L421F | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV50058606; called by muse, varscan2
- ARFGEF2 | c.4963G>C p.E1655Q | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV64215656; called by muse, mutect2, varscan2
- ARHGEF5 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 24/370 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99282850; called by muse, mutect2
- ARID2 | c.5364-1G>A p.X1788_splice | Splice Site (SNP) | VAF 3/36 reads (8%) | catalogued as COSV100535516, COSV100536272; called by muse, mutect2
- ARMC10 | c.880G>C p.E294Q | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.678); catalogued as COSV58524296; called by muse, mutect2
- ARMC6 | c.1372G>A p.E458K (on ENST00000392336; = p.E433K on NM_033415.4) | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV54184729; called by muse, mutect2, varscan2
- AS3MT | c.171-1G>T p.X57_splice | Splice Site (SNP) | VAF 16/68 reads (24%) | catalogued as COSV54919383; called by muse, mutect2, varscan2
- ASAP1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 39/140 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); catalogued as rs1173914668, COSV63045529, COSV63055139; called by muse, mutect2, varscan2
- ASTN2 | c.2894C>T p.S965L (on ENST00000313400 / NM_001365069.1; = p.S914L on NM_014010.5) | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.626); catalogued as COSV56016044; called by muse, mutect2, varscan2
- ATM | c.620C>G p.S207C | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs876660296, COSV53728088, COSV53776998; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP10A | c.3127G>C p.D1043H | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV63525926; called by muse, mutect2, varscan2
- ATP10A | c.1046G>A p.G349E | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV63525937; called by muse, mutect2, varscan2
- ATP6V1H | c.837G>C p.E279D | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); catalogued as COSV62220778; called by muse, mutect2, varscan2
- ATP7B | c.2428G>A p.E810K | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as rs770020484, CM125005, COSV54445095; called by muse, mutect2, varscan2
- ATP8B1 | c.1471G>C p.E491Q | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV52180934; called by muse, mutect2, varscan2
- BCL9 | c.275G>C p.G92A | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.87); PolyPhen benign (0.138); catalogued as rs782267474, COSV52351034; called by muse, mutect2, varscan2
- BIRC5 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV56957809; called by muse, mutect2, varscan2
- BRD1 | c.103C>G p.Q35E | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.138); catalogued as COSV53462269; called by muse, mutect2, varscan2
- C16orf89 | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.096); catalogued as rs1378077750, COSV100280839; called by muse, mutect2
- C1orf112 | c.173C>G p.T58R | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.391); catalogued as COSV53683359; called by muse, mutect2, varscan2
- C20orf194 | c.1829C>G p.S610* | Nonsense Mutation (SNP) | VAF 11/65 reads (17%) | catalogued as COSV99330793; called by muse, mutect2, varscan2
- C2CD2 | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as rs750064009, COSV61598848, COSV61600730; called by muse, mutect2, varscan2
- C2CD2L | c.1639C>G p.Q547E | Missense Mutation (SNP) | VAF 62/132 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.12); catalogued as rs559481720, COSV60884964; called by muse, mutect2, varscan2
- C6orf58 | c.79G>T p.E27* | Nonsense Mutation (SNP) | VAF 36/118 reads (31%) | catalogued as COSV100314890; called by muse, mutect2, varscan2
- CA14 | c.715G>T p.E239* | Nonsense Mutation (SNP) | VAF 21/112 reads (19%) | catalogued as rs782581132, COSV99354408, COSV99354452; called by muse, mutect2, varscan2
- CACHD1 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.051); catalogued as rs756222350, COSV51560844; called by muse, mutect2, varscan2
- CALD1 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.188); catalogued as COSV62655167; called by muse, mutect2, varscan2
- CALHM4 | c.739C>A p.R247S (on ENST00000368596 / NM_001366078.1; = p.R61S on NM_153036.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.355); catalogued as COSV63985834, COSV63986020; called by muse, mutect2, varscan2
- CAPRIN2 | c.1876C>G p.Q626E | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.725); catalogued as COSV51836135, COSV99195524; called by muse, mutect2, varscan2
- CCDC151 | c.1176G>C p.K392N | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs775975150, COSV62699350; called by mutect2, varscan2
- CCDC82 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.494); catalogued as COSV53595762; called by muse, mutect2, varscan2
- CCT6A | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV51907982; called by muse, mutect2, varscan2
- CDC14B | c.1368G>C p.Q456H | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV55795060; called by muse, mutect2, varscan2
- CDC6 | c.261C>G p.H87Q | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV52931644; called by muse, varscan2
- CDK8 | c.211C>G p.R71G | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV67421862, COSV67423395; called by muse, mutect2, varscan2
- CEP89 | c.946G>C p.D316H | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV59868264; called by muse, mutect2, varscan2
- CEP89 | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 9/56 reads (16%) | catalogued as rs1413775052, COSV99993505; called by muse, mutect2, varscan2
- CEPT1 | c.1143C>G p.F381L | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62960305; called by muse, mutect2, varscan2
- CHRDL2 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99733627, COSV99733811; called by muse, mutect2
- CLDN3 | c.438C>A p.F146L | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV67777457; called by muse, mutect2, varscan2
- CNTN2 | c.1294C>G p.R432G | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV59348735, COSV59353565; called by muse, mutect2, varscan2
- COLGALT1 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.284); catalogued as rs1480898944, COSV53111822; called by muse, mutect2, varscan2
- CTNND1 | c.2274_2278del p.L759Rfs*12 (on ENST00000399050 / NM_001085458.2; = p.L753Rfs*12 on NM_001331.3) | Frame Shift Del (DEL) | VAF 31/117 reads (26%) | catalogued as COSV62386571; called by mutect2, pindel, varscan2
- CTRL | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV52125163; called by muse, mutect2, varscan2
- DCC | c.1213G>C p.E405Q | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as COSV59140985; called by muse, mutect2, varscan2
- DCLRE1A | c.1741G>C p.E581Q | Missense Mutation (SNP) | VAF 25/197 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV63748203; called by muse, mutect2, varscan2
- DDX3X | c.1892G>A p.R631K (on ENST00000399959; = p.R632K on NM_001356.5) | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.04); catalogued as COSV67863768, COSV67864414, COSV67864628; called by muse, mutect2, varscan2
- DGKE | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV52351650; called by muse, mutect2, varscan2
- DLEC1 | c.850G>C p.E284Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs977774630, COSV57307670; called by muse, varscan2
- DMTN | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.229); catalogued as COSV56114838; called by muse, mutect2, varscan2
- DNAH8 | c.190C>G p.P64A | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as COSV59484666; called by muse, varscan2
- DNAH8 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (0.9); PolyPhen benign (0.028); catalogued as rs1291968591, COSV59484682; called by muse, varscan2
- DNAJC13 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.13); catalogued as COSV53453347; called by muse, mutect2, varscan2
- DPPA4 | c.879G>A p.R293= | Splice Region (SNP) | VAF 85/232 reads (37%) | catalogued as COSV59511885, COSV59512452; called by muse, mutect2, varscan2
- DYNC1I1 | c.1354G>A p.V452I | Missense Mutation (SNP) | VAF 63/217 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.275); catalogued as rs748814410, COSV61455179; called by muse, mutect2, varscan2
- DYRK1B | c.979G>C p.E327Q | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.48); catalogued as COSV59915641; called by muse, mutect2, varscan2
- EEF1G | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV100240395; called by muse, mutect2, varscan2
- EFCAB1 | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV50620300; called by muse, mutect2, varscan2
- EHBP1 | c.2932G>C p.E978Q | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.34); catalogued as COSV50442727, COSV99859661; called by muse, mutect2, varscan2
- EIF2B4 | c.708G>A p.V236= (on ENST00000347454 / NM_001034116.2; = p.V235= on NM_015636.3) | Splice Region (SNP) | VAF 18/87 reads (21%) | catalogued as COSV52011137; called by muse, mutect2, varscan2
- EPG5 | c.6715G>C p.E2239Q | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV56356829; called by muse, mutect2, varscan2
- ERBB3 | c.1741G>C p.D581H | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV57264725; called by muse, mutect2, varscan2
- ERBB4 | c.3227G>A p.G1076E | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.112); catalogued as COSV61487239; called by muse, mutect2, varscan2
- ERCC6L | c.2213C>T p.S738F | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.564); catalogued as COSV57822247, COSV57822618; called by muse, mutect2, varscan2
- ERVW-1 | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.74); PolyPhen benign (0.295); catalogued as rs773801539, COSV71259650; called by muse, mutect2, varscan2
- EZR | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1310991721, COSV61456504; called by muse, mutect2, varscan2
- FABP9 | c.320G>C p.R107T | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66911889; called by muse, varscan2
- FABP9 | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV66911892; called by muse, varscan2
- FAM76A | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50550070; called by muse, mutect2, varscan2
- FANCD2 | c.55G>T p.D19Y | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV55047680; called by muse, mutect2, varscan2
- FN1 | c.6819G>A p.M2273I (on ENST00000359671 / NM_001365524.2; = p.M2242I on NM_002026.4) | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.369); catalogued as rs1372226584, COSV60565626; called by muse, mutect2, varscan2
- FOCAD | c.1746G>C p.E582D | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); catalogued as COSV58108699; called by muse, mutect2, varscan2
- FREM2 | c.5916G>C p.E1972D | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54831002; called by muse, mutect2, varscan2
- FRMPD2 | c.2045C>G p.S682* | Nonsense Mutation (SNP) | VAF 26/104 reads (25%) | catalogued as COSV100563850; called by muse, mutect2, varscan2
- FRS2 | c.1222G>C p.E408Q | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV54726845; called by muse, varscan2
- FRS2 | c.1288G>C p.E430Q | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.377); catalogued as COSV54724513, COSV54730275; called by muse, varscan2
- FTSJ3 | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 15/72 reads (21%) | catalogued as COSV100037320; called by muse, mutect2, varscan2
- G6PD | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as CD930988, COSV63704872; called by muse, mutect2, varscan2
- GABARAP | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV56641784, COSV56643163; called by muse, mutect2, varscan2
- GADD45GIP1 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs1459612190, COSV57539956; called by muse, mutect2, varscan2
- GALNS | c.1238G>A p.R413K | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374798170, COSV51940975; called by muse, mutect2
- GALNT15 | c.974C>A p.S325* | Nonsense Mutation (SNP) | VAF 46/130 reads (35%) | catalogued as COSV100327684; called by muse, mutect2, varscan2
- GAPVD1 | c.4237G>A p.E1413K (on ENST00000394104; = p.E1422K on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.22); catalogued as COSV52928054; called by muse, mutect2, varscan2
- GHITM | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.836); catalogued as COSV100930085; called by muse, mutect2
- GOPC | c.546G>C p.L182F | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as COSV50005044; called by muse, mutect2, varscan2
- GPATCH8 | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV59199129; called by muse, mutect2, varscan2
- GRIN3B | c.1366C>G p.L456V | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.336); catalogued as COSV52263961; called by muse, mutect2, varscan2
- H4C12 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.243); catalogued as COSV100694786; called by muse, mutect2, varscan2
- HERC4 | c.1974C>G p.I658M (on ENST00000395198 / NM_022079.3; = p.I650M on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV53275996; called by muse, mutect2, varscan2
- HLA-DPB1 | c.264G>T p.W88C | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as COSV69604350; called by muse, mutect2, varscan2
- HPGDS | c.274G>T p.V92L | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as COSV54776531; called by muse, mutect2, varscan2
- HSD17B2 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1567586319, COSV52274693, COSV52277315; called by muse, mutect2, varscan2
- HSPB7 | c.74C>G p.S25C | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100317931; called by muse, mutect2
- HTR1D | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.123); catalogued as rs766858162, COSV100024808, COSV100024892; called by muse, mutect2
- IGFBP3 | c.528G>C p.K176N | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV51873652; called by muse, mutect2, varscan2
- IGLC2 | c.191_193del p.N64del | In Frame Del (DEL) | VAF 7/59 reads (12%) | catalogued as rs773466513; called by pindel, varscan2
- IKBIP | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV54491348; called by muse, mutect2, varscan2
- IL20RB | c.510G>C p.W170C | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59050063; called by muse, mutect2, varscan2
- ILF3 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.909); catalogued as rs750756508, COSV99139753; called by muse, mutect2
- INO80 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1336601411, COSV62737965, COSV62743139; called by muse, mutect2, varscan2
- INO80 | c.1684G>A p.E562K | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV62743150; called by muse, mutect2, varscan2
- INPP4B | c.312C>G p.I104M | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV53748242; called by muse, mutect2, varscan2
- INTS7 | c.380G>A p.G127E | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1329281724, COSV65345714; called by muse, mutect2, varscan2
- INTS8 | c.1440G>C p.Q480H | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV58253707; called by muse, mutect2, varscan2
- IQCG | c.950G>C p.R317T | Missense Mutation (SNP) | VAF 10/350 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.347); catalogued as COSV54566818; called by muse, mutect2
- ITGA2 | c.2041T>C p.F681L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as COSV56867470; called by muse, mutect2, varscan2
- ITIH1 | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs200000763, COSV56252801; called by muse, mutect2, varscan2
- ITLN2 | c.539G>A p.R180K | Missense Mutation (SNP) | VAF 560/656 reads (85%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV63537640, COSV63538340; called by muse, varscan2
- KATNIP | c.3160C>T p.R1054W | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs761854517, COSV55188681; called by muse, mutect2, varscan2
- KBTBD2 | c.465G>A p.M155I | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.096); catalogued as rs1226609015, COSV58364463; called by muse, mutect2, varscan2
- KCNA4 | c.182C>G p.S61C | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.356); catalogued as COSV60250673, COSV60251772; called by muse, mutect2, varscan2
- KCNK3 | c.589C>T p.L197F | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV57194941; called by muse, mutect2, varscan2
- KDM3B | c.5035G>A p.D1679N | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58696053; called by muse, mutect2, varscan2
- KDM5B | c.3690G>T p.E1230D | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as COSV52513921; called by muse, mutect2, varscan2
- KIDINS220 | c.5181G>C p.E1727D | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.015); catalogued as rs749423918, COSV56760080; called by muse, mutect2, varscan2
- KIF26B | c.1891G>A p.E631K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1361147956, COSV100832500; called by muse, mutect2
- KIT | c.2597G>A p.G866E | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55391351, COSV55408604; called by muse, mutect2, varscan2
- KMT2C | c.8362C>T p.Q2788* | Nonsense Mutation (SNP) | VAF 33/101 reads (33%) | catalogued as COSV51502576; called by muse, mutect2, varscan2
- KMT2D | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV56492502; called by muse, mutect2, varscan2
- KRT10 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV54091752; called by muse, mutect2, varscan2
- KRTAP19-5 | c.119G>A p.G40D | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.801); catalogued as COSV61859773; called by muse, mutect2, varscan2
- LAMA4 | c.4309C>G p.P1437A (on ENST00000230538 / NM_001105206.3; = p.P1430A on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.99); PolyPhen benign (0.005); catalogued as COSV57906000; called by muse, mutect2, varscan2
- LENG9 | c.1008G>T p.Q336H | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.083); catalogued as COSV56620160; called by muse, mutect2, varscan2
- LIPE | c.2695G>C p.E899Q | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV54925994; called by muse, mutect2, varscan2
- LIPH | c.1273C>T p.Q425* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as COSV99956012; called by muse, mutect2, varscan2
- LOXL1 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs141057976; called by muse, mutect2, varscan2
- LYST | c.6889G>A p.E2297K | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as rs1180470841, COSV67715080; called by muse, mutect2, varscan2
- MAB21L2 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV58263812; called by muse, mutect2, varscan2
- MACF1 | c.8026C>T p.Q2676* | Nonsense Mutation (SNP) | VAF 20/65 reads (31%) | catalogued as COSV99244593; called by muse, mutect2, varscan2
- MAGEA3 | c.450C>G p.I150M | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64755979, COSV64756093; called by muse, mutect2, varscan2
- MARVELD2 | c.1551G>C p.K517N | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57782627; called by muse, mutect2, varscan2
- MAST1 | c.3482C>T p.S1161L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as rs1459942141, COSV52256299; called by muse, mutect2, varscan2
- MATK | c.442G>A p.E148K (on ENST00000310132 / NM_139355.3; = p.E149K on NM_002378.4) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59557042; called by muse, mutect2
- MBNL2 | c.703C>T p.H235Y | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59126313; called by muse, mutect2, varscan2
- MBOAT1 | c.1393C>G p.L465V | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV61128301; called by muse, mutect2, varscan2
- MC3R | c.280G>C p.E94Q | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54765170, COSV99710792; called by muse, mutect2, varscan2
- MCM2 | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 80/212 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV54037880; called by muse, mutect2, varscan2
- MCM7 | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV57999423; called by muse, mutect2, varscan2
- MED13 | c.1894C>G p.Q632E | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.344); catalogued as COSV67267569; called by muse, mutect2, varscan2
- METTL24 | c.997C>T p.H333Y | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as COSV58824885; called by muse, mutect2, varscan2
- MGRN1 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs747300145, COSV52149027; called by muse, mutect2, varscan2
- MMP1 | c.480G>A p.M160I | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); catalogued as COSV59512070; called by muse, mutect2, varscan2
- MPI | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.434); catalogued as COSV60397760; called by muse, mutect2, varscan2
- MRPS28 | c.305G>A p.G102E | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52566007; called by muse, mutect2, varscan2
- MRPS5 | c.646G>C p.E216Q | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV55535608, COSV99720866; called by muse, mutect2, varscan2
- MSR1 | c.797G>A p.R266K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50541380; called by muse, mutect2
- MST1R | c.3079G>A p.D1027N | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.029); catalogued as COSV56574826; called by muse, mutect2, varscan2
- MTOR | c.5598G>C p.Q1866H | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.986); catalogued as COSV63879162; called by muse, mutect2
- MUC16 | c.2063C>G p.S688* | Nonsense Mutation (SNP) | VAF 15/90 reads (17%) | catalogued as COSV101200021, COSV67474509; called by muse, mutect2, varscan2
- MVP | c.1597G>A p.D533N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1397667778, COSV62421978; called by muse, mutect2, varscan2
- MYO1F | c.3196G>A p.E1066K | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as rs777571005, COSV57791838; called by muse, mutect2, varscan2
- MYO1G | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51857395; called by muse, mutect2, varscan2
- MYO3B | c.1930C>A p.L644M | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58719458; called by muse, mutect2
- MYO9A | c.3124C>G p.L1042V | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV61859243; called by muse, mutect2, varscan2
- NAT8 | c.548C>G p.S183C | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV55542117, COSV55543225; called by muse, mutect2, varscan2
- NAV2 | c.7252G>A p.E2418K (on ENST00000396087 / NM_001244963.2; = p.E2359K on NM_145117.5) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV60666231; called by muse, mutect2, varscan2
- NBEAL2 | c.5818G>A p.E1940K | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV52763404; called by muse, mutect2, varscan2
- NBEAL2 | c.5965G>C p.E1989Q | Missense Mutation (SNP) | VAF 60/288 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs946100525, COSV52763418; called by muse, varscan2
- NFIC | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); catalogued as rs755493282, COSV59417506; called by muse, mutect2, varscan2
- NID1 | c.1289C>T p.S430F | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51615792, COSV51630015; called by muse, mutect2, varscan2
- NISCH | c.3368C>T p.S1123L | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs200762525, COSV61902697; called by muse, mutect2, varscan2
- NOTCH4 | c.5929G>A p.E1977K | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.572); catalogued as rs1239036035, COSV66679314, COSV66679913; called by muse, mutect2, varscan2
- NR1H2 | c.978C>G p.I326M | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV53802761; called by muse, varscan2
- NSFL1C | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV53795506; called by muse, mutect2, varscan2
- NUP205 | c.5630G>T p.R1877L | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV53667133; called by muse, mutect2
- NUP58 | c.139C>T p.L47F | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV67752187; called by muse, mutect2, varscan2
- OAS1 | c.875C>T p.T292M | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.501); catalogued as rs778367989, COSV52539103; called by muse, mutect2, varscan2
- OLA1 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52974736; called by muse, mutect2, varscan2
- ONECUT2 | c.1465C>G p.L489V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.057); catalogued as COSV72153376; called by muse, mutect2, varscan2
- OR6B1 | c.878G>C p.R293P | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as COSV68770091, COSV68770685; called by muse, mutect2, varscan2
- OR9I1 | c.593T>C p.V198A | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV56927630; called by muse, mutect2, varscan2
- PAK3 | c.530C>G p.S177C (on ENST00000262836 / NM_001324328.2; = p.S162C on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV53275415; called by muse, varscan2
- PAX2 | c.743G>A p.R248Q (on ENST00000428433 / NM_003987.5; = p.R225Q on NM_000278.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/234 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs765955789, COSV62291074; called by muse, mutect2, varscan2
- PCDHB12 | c.591C>G p.D197E | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.794); catalogued as COSV53401635; called by muse, mutect2, varscan2
- PCSK6 | c.2662G>A p.E888K | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.118); catalogued as COSV61862082; called by muse, mutect2, varscan2
- PDCD1 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs750496363, COSV57691950, COSV57692171; called by muse, mutect2, varscan2
- PDCD6IP | c.267C>G p.I89M | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV56246227; called by muse, mutect2, varscan2
- PEAK3 | c.68C>T p.T23M | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs141253643; called by muse, mutect2, varscan2
- PHKB | c.2081C>G p.S694* | Nonsense Mutation (SNP) | VAF 39/129 reads (30%) | catalogued as COSV100067217; called by muse, mutect2, varscan2
- PIGM | c.200C>A p.S67* | Nonsense Mutation (SNP) | VAF 23/64 reads (36%) | catalogued as COSV100928045; called by muse, mutect2, varscan2
- PITPNM1 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs753677101, COSV62709211; called by muse, varscan2
- PITPNM2 | c.2926G>A p.E976K | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV54909785; called by muse, varscan2
- PLG | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as rs369196761; called by muse, mutect2, varscan2
- PMFBP1 | c.2263G>A p.E755K (on ENST00000537465; = p.E750K on NM_031293.3) | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs538461095, COSV52820723, COSV52822625; called by muse, mutect2, varscan2
- PPT2 | c.120C>G p.I40M | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52999820; called by muse, mutect2, varscan2
- PREPL | c.2155G>A p.E719K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs892455452, COSV53219677; called by muse, mutect2, varscan2
- PRKCH | c.1738G>C p.D580H | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100273095, COSV60653021; called by muse, mutect2, varscan2
- PRLR | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51495960; called by muse, mutect2, varscan2
- PTGS2 | c.1452C>G p.I484M | Missense Mutation (SNP) | VAF 367/442 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66572076; called by muse, mutect2, varscan2
- PUM1 | c.2854G>A p.E952K | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV57092087; called by muse, mutect2, varscan2
- PUM1 | c.1112C>G p.S371* | Nonsense Mutation (SNP) | VAF 20/137 reads (15%) | catalogued as COSV99928106; called by muse, mutect2, varscan2
- PUM3 | c.207G>C p.K69N | Missense Mutation (SNP) | VAF 141/252 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV67397640; called by muse, mutect2, varscan2
- PXK | c.1692G>C p.L564F | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57058145; called by muse, mutect2, varscan2
- RAD21 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52064698; called by muse, mutect2, varscan2
- RARS2 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs201899366, COSV57638114, COSV57641021; called by muse, mutect2, varscan2
- RENBP | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.146); catalogued as COSV60078571; called by muse, mutect2, varscan2
- REV3L | c.8741G>C p.R2914T | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV62624186; called by muse, mutect2, varscan2
- REV3L | c.8336A>G p.Y2779C | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62624196; called by muse, mutect2, varscan2
- RNF112 | c.1304C>G p.S435* | Nonsense Mutation (SNP) | VAF 10/23 reads (43%) | catalogued as COSV71327013, COSV71327094; called by muse, mutect2, varscan2
- RNF112 | c.1513C>A p.L505M | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV71327135; called by muse, mutect2, varscan2
- RTTN | c.2519C>T p.S840L | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55343376; called by muse, mutect2
- SCN10A | c.3943G>A p.D1315N | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs147640811; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCUBE1 | c.562G>C p.D188H | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.752); catalogued as COSV51809353, COSV51809926, COSV51816866; called by muse, mutect2, varscan2
- SF3A3 | c.596G>C p.R199T | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV65956962; called by muse, mutect2, varscan2
- SKA3 | c.1049C>T p.S350F | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100006424, COSV53437458; called by muse, varscan2
- SLC20A2 | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60607525; called by muse, mutect2, varscan2
- SLC2A5 | c.358A>G p.R120G | Missense Mutation (SNP) | VAF 67/152 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs374797166; called by muse, mutect2, varscan2
- SLC35F3 | c.1179G>C p.K393N (on ENST00000366617 / NM_001300845.1; = p.K462N on NM_173508.4) | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV64021979; called by muse, mutect2, varscan2
- SLC49A4 | c.704-1G>C p.X235_splice | Splice Site (SNP) | VAF 101/255 reads (40%) | catalogued as COSV53749933; called by muse, varscan2
- SLC49A4 | c.824G>C p.R275T | Missense Mutation (SNP) | VAF 86/178 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV53749942; called by muse, varscan2
- SLC6A17 | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV58997346; called by muse, mutect2, varscan2
- SLC9A8 | c.1735G>C p.E579Q | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.756); catalogued as COSV100846274; called by muse, mutect2
- SMC3 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV62422748; called by muse, mutect2, varscan2
- SND1 | c.1685G>A p.R562K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.752); catalogued as rs1159601136, COSV61244278; called by muse, mutect2, varscan2
- SORCS3 | c.611C>A p.S204* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as rs1254366245, COSV100865158, COSV63815498; called by muse, mutect2, varscan2
- SP140 | c.877G>C p.E293Q | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV59455800; called by muse, mutect2, varscan2
- SPPL2A | c.1486C>T p.Q496* | Nonsense Mutation (SNP) | VAF 14/69 reads (20%) | catalogued as rs1371167358, COSV55940636; called by muse, mutect2, varscan2
- SPRTN | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV50480202; called by muse, mutect2, varscan2
- SPSB2 | c.171C>G p.I57M | Missense Mutation (SNP) | VAF 73/170 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV51290479; called by muse, mutect2, varscan2
- SPTAN1 | c.4427C>G p.S1476* | Nonsense Mutation (SNP) | VAF 94/176 reads (53%) | catalogued as COSV100823611; called by muse, mutect2, varscan2
- SRM | c.622G>C p.E208Q | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1448571929, COSV65384705, COSV65385045; called by muse, mutect2, varscan2
- SRRM2 | c.2077C>T p.R693W | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.432); catalogued as rs759041122, COSV57081333; called by muse, mutect2, varscan2
- STAB1 | c.5478C>G p.F1826L | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58740900, COSV58743870; called by muse, mutect2, varscan2
- SUPT6H | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as COSV58932049; called by muse, mutect2, varscan2
- SZT2 | c.9564-7_9569del p.X3188_splice (on ENST00000634258 / NM_001365999.1; = p.X3131_splice on NM_015284.4) | Splice Site (DEL) | VAF 8/36 reads (22%) | catalogued as COSV65095551; called by mutect2, pindel, varscan2
- TANC1 | c.4675C>T p.Q1559* | Nonsense Mutation (SNP) | VAF 11/89 reads (12%) | catalogued as COSV99714035; called by muse, mutect2, varscan2
- TAOK1 | c.1225G>C p.E409Q | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.254); catalogued as COSV55599713; called by muse, mutect2, varscan2
- TBP | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.3); catalogued as rs1190072930, COSV100027327, COSV57833031; called by muse, mutect2
- TDRD9 | c.2067G>A p.W689* | Nonsense Mutation (SNP) | VAF 18/54 reads (33%) | catalogued as COSV100175172; called by muse, mutect2, varscan2
- TGFBR1 | c.557C>T p.T186M | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs144313652; called by muse, mutect2, varscan2
- THAP11 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1250433902, COSV54647671; called by muse, mutect2, varscan2
- TM9SF4 | c.921G>C p.K307N | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV54112032; called by muse, varscan2
- TMEFF1 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as COSV58497945; called by muse, mutect2, varscan2
- TMEM202 | c.785G>C p.R262T | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV58983936; called by muse, mutect2, varscan2
- TMEM241 | c.275G>C p.R92T | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV101271667, COSV67245885; called by muse, mutect2, varscan2
- TMEM26 | c.580G>T p.E194* | Nonsense Mutation (SNP) | VAF 11/64 reads (17%) | catalogued as COSV99515657; called by muse, mutect2, varscan2
- TMEM39B | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60379039, COSV60381634; called by muse, mutect2, varscan2
- TMEM52B | c.232G>A p.D78N (on ENST00000381923 / NM_001079815.1; = p.D58N on NM_153022.4) | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1171656534, COSV53729914; called by muse, mutect2, varscan2
- TMPO | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as rs1439919068, COSV100587760; called by muse, mutect2, varscan2
- TMPRSS2 | c.953C>G p.S318C | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV59828007; called by muse, mutect2, varscan2
- TNIK | c.2054G>C p.R685T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.349); catalogued as COSV52698277; called by muse, mutect2, varscan2
- TNIP2 | c.1210C>A p.Q404K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as rs1395418193, COSV59570350; called by muse, mutect2, varscan2
- TPX2 | c.2000G>A p.R667K | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55923376; called by muse, mutect2
- TRPM2 | c.1586C>T p.S529F | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV55978224; called by muse, mutect2, varscan2
- TSHZ3 | c.1449G>C p.E483D | Missense Mutation (SNP) | VAF 71/307 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1381466429, COSV53672270, COSV53684672; called by muse, mutect2, varscan2
- TTC7A | c.2071G>A p.E691K | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs760148843, COSV55416054; called by muse, mutect2, varscan2
- TTN | c.85190C>T p.S28397L (on ENST00000591111; = p.S20973L on NM_003319.4) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | PolyPhen benign (0.001); catalogued as rs1035231480, COSV60389705; called by muse, mutect2, varscan2
- TTN | c.64912C>T p.H21638Y (on ENST00000591111; = p.H14214Y on NM_003319.4) | Missense Mutation (SNP) | VAF 3/41 reads (7%) | PolyPhen benign (0.009); catalogued as COSV100614672; called by muse, mutect2
- TTN | c.21169A>G p.T7057A (on ENST00000591111; = p.T6130A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | PolyPhen benign (0.001); catalogued as COSV60389743; called by mutect2, varscan2
- TTN | c.2737G>A p.E913K (on ENST00000591111; = p.E867K on NM_003319.4) | Missense Mutation (SNP) | VAF 34/89 reads (38%) | PolyPhen benign (0.311); catalogued as rs879217756, COSV59876008, COSV59921102; called by muse, mutect2, varscan2
- TTN | c.1316G>C p.R439T | Missense Mutation (SNP) | VAF 23/119 reads (19%) | PolyPhen probably damaging (0.99); catalogued as COSV60389812; called by muse, mutect2, varscan2
- UBR2 | c.1443C>G p.L481= | Splice Region (SNP) | VAF 25/87 reads (29%) | catalogued as COSV65753005; called by muse, mutect2, varscan2
- UNC13B | c.2938G>A p.E980K | Missense Mutation (SNP) | VAF 70/130 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV65939209; called by muse, mutect2, varscan2
- UNC5B | c.725T>G p.I242S | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV58981923; called by muse, mutect2, varscan2
- USP33 | c.444+2T>C p.X148_splice | Splice Site (SNP) | VAF 23/105 reads (22%) | catalogued as COSV62471767; called by muse, mutect2, varscan2
- USP54 | c.1657C>T p.R553C | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs370485233, COSV60445809; called by muse, mutect2, varscan2
- VAT1L | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.977); catalogued as COSV56817288; called by muse, mutect2, varscan2
- VCAM1 | c.1882G>A p.V628I | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.981); catalogued as COSV54122660; called by muse, mutect2, varscan2
- WDR45 | c.553C>G p.P185A (on ENST00000376372 / NM_001029896.2; = p.P186A on NM_007075.3) | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.06); PolyPhen benign (0.345); catalogued as COSV100540254; called by muse, mutect2, varscan2
- WDR7 | c.3041G>A p.R1014Q | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as rs758629275, COSV54364670; called by mutect2, varscan2
- ZBTB11 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1343606818, COSV57247244; called by muse, mutect2, varscan2
- ZBTB18 | c.67C>T p.L23F | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62398528; called by muse, mutect2, varscan2
- ZBTB21 | c.3046G>A p.E1016K | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as COSV100177136; called by muse, mutect2
- ZBTB21 | c.2785G>C p.E929Q | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60406053; called by muse, varscan2
- ZBTB21 | c.2748G>C p.K916N | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.408); catalogued as COSV60406060; called by muse, varscan2
- ZBTB21 | c.2578G>C p.D860H | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60406067; called by muse, mutect2, varscan2
- ZBTB21 | c.1977G>C p.K659N | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV60406073; called by muse, mutect2, varscan2
- ZBTB48 | c.1508G>C p.R503P | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV66554194, COSV66554360; called by muse, mutect2, varscan2
- ZC3HAV1 | c.919C>T p.R307W | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.332); catalogued as rs756632011, COSV54301840; called by muse, mutect2, varscan2
- ZMYM1 | c.2119G>A p.D707N | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as COSV63254091; called by muse, mutect2, varscan2
- ZNF131 | c.1573C>G p.L525V (on ENST00000509156 / NM_001330707.2; = p.L491V on NM_003432.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.031); catalogued as COSV61004769; called by muse, mutect2, varscan2
- ZNF284 | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as rs1267051342, COSV69690859; called by muse, mutect2, varscan2
- ZNF774 | c.676C>T p.Q226* | Nonsense Mutation (SNP) | VAF 12/68 reads (18%) | catalogued as rs757666272, COSV100586348; called by muse, mutect2, varscan2
- ZNFX1 | c.5674G>A p.E1892K | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65601055; called by muse, mutect2, varscan2
- ZP2 | c.2021C>A p.S674* | Nonsense Mutation (SNP) | VAF 13/83 reads (16%) | catalogued as COSV54813186; called by muse, mutect2, varscan2
- ACACA | c.1921C>T p.Q641* | Nonsense Mutation (SNP) | VAF 33/172 reads (19%) | called by muse, mutect2, varscan2
- GPATCH1 | c.2009C>G p.S670* | Nonsense Mutation (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2
- PPIAL4A | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | called by mutect2, varscan2
- ABCA3 | c.4701C>T p.I1567= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as rs779460194, COSV57060975; called by muse, mutect2, varscan2
- ABCA7 | c.3303G>A p.L1101= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV99565856; called by muse, mutect2
- ACOX2 | c.408C>G p.A136= | Silent (SNP) | VAF 39/163 reads (24%) | catalogued as COSV57151308; called by muse, mutect2, varscan2
- ADAMTS10 | c.747G>A p.K249= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as COSV54352340; called by muse, varscan2
- ADAMTS19 | c.765C>G p.L255= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV99178894; called by muse, mutect2
- ADAMTS4 | c.480C>T p.L160= | Silent (SNP) | VAF 22/806 reads (3%) | catalogued as COSV63488875; called by muse, mutect2
- ADGRE5 | c.1206C>G p.L402= (on ENST00000242786 / NM_078481.4; = p.L309= on NM_001784.5) | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as COSV54412086, COSV54415444; called by muse, mutect2, varscan2
- AGO2 | c.1938C>T p.V646= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV99595771; called by muse, mutect2
- AL592490.1 | c.861G>C p.V287= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV69428290; called by muse, mutect2, varscan2
- ARMC6 | c.1110G>A p.T370= (on ENST00000392336; = p.T345= on NM_033415.4) | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as rs768973848, COSV54184709; called by muse, mutect2, varscan2
- ATP8B3 | c.3271C>T p.L1091= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV59549462; called by muse, mutect2, varscan2
- BCDIN3D | c.174C>T p.L58= | Silent (SNP) | VAF 14/105 reads (13%) | catalogued as COSV61702921; called by muse, mutect2, varscan2
- BOLA1 | c.6G>A p.L2= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV64967714; called by muse, mutect2, varscan2
- BPTF | c.8226C>T p.F2742= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs782185025, COSV58848412; called by muse, mutect2, varscan2
- C1orf87 | c.1470G>C p.L490= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV100967124, COSV64599162; called by muse, mutect2, varscan2
- CACHD1 | c.2007C>G p.L669= | Silent (SNP) | VAF 19/130 reads (15%) | catalogued as COSV51560855; called by muse, mutect2, varscan2
- CATSPER4 | c.54C>G p.L18= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV100128395; called by muse, mutect2
- CCL8 | c.117C>T p.I39= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs752495969, COSV67014129; called by muse, mutect2, varscan2
- CDC42BPA | c.3588G>C p.L1196= (on ENST00000334218 / NM_001366019.2; = p.L1183= on NM_003607.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 62/206 reads (30%) | catalogued as COSV62023482; called by muse, mutect2, varscan2
- CEBPZ | c.2340G>A p.P780= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as rs367592440; called by muse, mutect2, varscan2
- CHD5 | c.2464C>T p.L822= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs1333657170, COSV52426584; called by muse, mutect2, varscan2
- CHRNA4 | c.501C>T p.F167= | Silent (SNP) | VAF 28/118 reads (24%) | catalogued as rs374602963; ClinVar: likely benign; called by muse, mutect2, varscan2
- CLDN3 | c.261C>T p.I87= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs1240058163, COSV67777464; called by muse, mutect2, varscan2
- CNNM2 | c.2058C>T p.F686= | Silent (SNP) | VAF 27/169 reads (16%) | catalogued as rs368187595; called by muse, mutect2, varscan2
- CNTN2 | c.1293C>A p.A431= | Silent (SNP) | VAF 56/192 reads (29%) | catalogued as COSV59353560; called by muse, mutect2, varscan2
- CPT1A | c.915C>T p.S305= | Silent (SNP) | VAF 7/93 reads (8%) | catalogued as rs763082846, COSV55761929; called by muse, mutect2
- CRHR2 | c.439C>T p.L147= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV59268291; called by muse, mutect2, varscan2
- CSNK1E | c.693G>A p.K231= | Silent (SNP) | VAF 29/147 reads (20%) | catalogued as rs761035222, COSV63290751, COSV63292237; called by muse, mutect2, varscan2
- CTSG | c.240G>A p.Q80= | Silent (SNP) | VAF 34/86 reads (40%) | catalogued as COSV53537103; called by muse, mutect2, varscan2
- DCDC1 | c.3231A>G p.E1077= (on ENST00000597505 / NM_001367979.1; = p.E184= on NM_020869.3) | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as COSV60313779; called by muse, mutect2, varscan2
- DCSTAMP | c.588C>T p.V196= | Silent (SNP) | VAF 41/135 reads (30%) | catalogued as COSV52580511; called by muse, mutect2, varscan2
- DENND1A | c.1914C>G p.L638= | Silent (SNP) | VAF 34/73 reads (47%) | catalogued as COSV65355861, COSV65357465; called by muse, mutect2, varscan2
- DIP2A | c.3495G>T p.V1165= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV59488293; called by muse, mutect2, varscan2
- DNAH5 | c.10314C>T p.L3438= | Silent (SNP) | VAF 54/151 reads (36%) | catalogued as rs886376710, COSV54219297; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAI4 | c.2025C>T p.I675= | Silent (SNP) | VAF 41/204 reads (20%) | catalogued as rs151194061, COSV64031810; called by muse, mutect2, varscan2
- EFHB | c.1848C>T p.F616= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs1348448310, COSV55554462; called by muse, mutect2, varscan2
- EHMT1 | c.3561C>T p.I1187= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs1002117245, COSV66044943; ClinVar: likely benign; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1324C>T p.L442= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV100349165; called by muse, mutect2
- ERICH3 | c.3066C>G p.A1022= | Silent (SNP) | VAF 20/131 reads (15%) | catalogued as COSV100444549, COSV58620443; called by muse, mutect2, varscan2
- ERICH6 | c.366G>A p.P122= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV99901697; called by muse, mutect2
- FES | c.765C>T p.I255= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV61001835; called by muse, mutect2, varscan2
- GDF7 | c.1083C>T p.L361= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs1247520712, COSV55348763; called by muse, mutect2, varscan2
- GIT1 | c.696C>T p.F232= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV56613247; called by muse, mutect2
- GLI4 | c.159G>A p.Q53= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs1172550347, COSV100391054; called by muse, mutect2, varscan2
- GPR17 | c.1083G>A p.L361= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as COSV55757449; called by muse, mutect2, varscan2
- GRHL2 | c.192C>T p.L64= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as rs746434474, COSV52555881, COSV99307854; called by muse, mutect2, varscan2
- GRIA2 | c.1548C>T p.F516= | Silent (SNP) | VAF 8/134 reads (6%) | catalogued as COSV52408581; called by muse, mutect2
- HAP1 | c.759C>T p.L253= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs1555591225, COSV100169707; called by muse, mutect2
- HTR6 | c.345C>T p.L115= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as COSV57033686, COSV57034854; called by muse, mutect2, varscan2
- IRS1 | c.1170C>T p.V390= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV59340226; called by muse, mutect2, varscan2
- ITLN2 | c.171G>A p.K57= | Silent (SNP) | VAF 236/285 reads (83%) | catalogued as COSV63538344; called by muse, mutect2, varscan2
- ITSN2 | c.99C>G p.L33= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as COSV61948189; called by muse, varscan2
- KCNJ3 | c.291C>T p.F97= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as rs780666205, COSV54545956; called by muse, mutect2, varscan2
- KCNK3 | c.354C>T p.I118= | Silent (SNP) | VAF 43/110 reads (39%) | catalogued as rs1390180986, COSV57194935; called by muse, mutect2, varscan2
- KIAA1549L | c.3747G>A p.V1249= (on ENST00000321505; = p.V1546= on NM_012194.3) | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV55775523, COSV99683577; called by muse, mutect2
- KIF21B | c.3174G>A p.L1058= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs527985183, COSV59767963; called by muse, mutect2, varscan2
- KLHL23 | c.657C>G p.L219= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs1413528256, COSV55870127; called by muse, mutect2, varscan2
- KMT5A | c.180G>A p.P60= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs755931632, COSV57863849, COSV57865113; called by muse, mutect2, varscan2
- LIMK2 | c.1554G>A p.L518= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV59184933; called by muse, mutect2, varscan2
- LSM7 | c.21G>A p.K7= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as rs1441487318, COSV53117085; called by muse, mutect2, varscan2
- LZTS2 | c.420G>A p.K140= | Silent (SNP) | VAF 37/131 reads (28%) | catalogued as COSV64653102; called by muse, mutect2, varscan2
- MBOAT1 | c.69C>T p.L23= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV61128306; called by muse, mutect2, varscan2
- MFSD11 | c.1173C>T p.F391= | Silent (SNP) | VAF 67/189 reads (35%) | catalogued as COSV60629265; called by muse, mutect2, varscan2
- MGAT3 | c.918C>T p.N306= | Silent (SNP) | VAF 55/123 reads (45%) | catalogued as COSV57869000; called by muse, mutect2, varscan2
- MST1R | c.2520G>A p.G840= | Silent (SNP) | VAF 25/139 reads (18%) | catalogued as COSV56564316; called by muse, mutect2, varscan2
- MTCL1 | c.4797G>A p.L1599= (on ENST00000306329 / NM_001378206.1; = p.L1280= on NM_015210.4) | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV60412705; called by muse, mutect2, varscan2
- MTTP | c.1233C>G p.L411= | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as rs1179169124, COSV55510454; called by muse, mutect2, varscan2
- MYLK | c.2283C>T p.L761= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as rs769054527, COSV60605532, COSV60624328; called by muse, mutect2, varscan2
- MYO5B | c.1284C>G p.L428= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV53219047; called by muse, mutect2, varscan2
- NME9 | c.720C>T p.D240= (on ENST00000333911 / NM_001349024.2; = p.D179= on NM_178130.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/323 reads (7%) | catalogued as rs377196410; called by muse, mutect2
- OLA1 | c.849G>A p.L283= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as COSV52974752; called by muse, mutect2, varscan2
- OR10Z1 | c.81C>G p.L27= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as COSV63523770, COSV63524947, COSV63526801; called by muse, mutect2, varscan2
- PCDHB16 | c.2163G>A p.S721= | Silent (SNP) | VAF 63/191 reads (33%) | catalogued as rs782496465, COSV53372306; called by muse, mutect2, varscan2
- PIK3C2B | c.3732C>T p.I1244= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as COSV65814630; called by muse, mutect2, varscan2
- PIK3C2B | c.2040C>T p.L680= | Silent (SNP) | VAF 50/147 reads (34%) | catalogued as COSV65814636; called by muse, mutect2, varscan2
- PITPNM1 | c.1725C>G p.L575= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV62710158; called by muse, mutect2, varscan2
- PKN3 | c.2604C>T p.L868= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV52580164; called by muse, mutect2, varscan2
- PKNOX1 | c.834C>G p.L278= | Silent (SNP) | VAF 4/64 reads (6%) | catalogued as COSV99372880; called by muse, mutect2
- PLCL1 | c.459C>T p.L153= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs1004769622, COSV70842298, COSV70881154; called by muse, mutect2, varscan2
- PLD6 | c.582C>T p.Y194= | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as rs142631639; called by muse, mutect2, varscan2
- PLXNB2 | c.5514C>G p.L1838= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV63784909; called by muse, mutect2, varscan2
- POMGNT1 | c.153C>T p.V51= | Silent (SNP) | VAF 47/282 reads (17%) | catalogued as COSV64341164; called by muse, mutect2, varscan2
- POP4 | c.552C>T p.F184= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs1429423731, COSV55677645; called by muse, mutect2, varscan2
- PPARD | c.87C>T p.L29= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs1288323044, COSV100283255, COSV61101740; called by muse, mutect2, varscan2
- PPP2R3B | c.456C>T p.F152= | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as rs759650886, COSV66814577; called by muse, mutect2, varscan2
- PRDM1 | c.1383C>A p.L461= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as COSV64844942, COSV64847292; called by muse, mutect2, varscan2
- PSMB7 | c.765C>T p.L255= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as rs1215461217, COSV52333090; called by muse, mutect2, varscan2
- PTGS2 | c.756C>G p.V252= | Silent (SNP) | VAF 252/298 reads (85%) | catalogued as COSV66572085; called by muse, mutect2, varscan2
- PTPRC | c.2523C>T p.F841= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs772146031, COSV61417460, COSV61421403; called by muse, mutect2, varscan2
- RIN2 | c.1623C>T p.L541= (on ENST00000255006 / NM_001242581.1; = p.L492= on NM_018993.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/144 reads (26%) | catalogued as COSV54795230; called by muse, mutect2, varscan2
- ROBO1 | c.2727C>T p.I909= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV71399108; called by muse, mutect2, varscan2
- RYR2 | c.1491C>T p.L497= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as rs774279425, COSV63678825; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCML2 | c.2004C>G p.L668= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV52625530; called by muse, mutect2, varscan2
- SETBP1 | c.2160C>A p.T720= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV56338793; called by muse, mutect2, varscan2
- SLC13A1 | c.1059C>T p.L353= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV52017635; called by muse, mutect2, varscan2
- SLC25A10 | c.474G>A p.R158= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV58972187; called by muse, mutect2, varscan2
- SLC32A1 | c.903C>T p.I301= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV54148155; called by muse, varscan2
- SLC32A1 | c.963C>T p.I321= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV54146997, COSV54148571, COSV99461750; called by muse, varscan2
- SLC45A4 | c.1845C>T p.Y615= (on ENST00000517878 / NM_001286646.2; = p.Y564= on NM_001080431.2) | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as rs1352275230, COSV50201774; called by muse, mutect2, varscan2
- SOGA1 | c.909C>G p.V303= | Silent (SNP) | VAF 45/135 reads (33%) | catalogued as COSV52932959; called by muse, mutect2, varscan2
- SPAG1 | c.2571G>A p.L857= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV52564042; called by muse, mutect2, varscan2
- SRL | c.1080C>T p.F360= | Silent (SNP) | VAF 32/132 reads (24%) | catalogued as COSV68424816; called by muse, mutect2, varscan2
- STAB1 | c.5133C>T p.P1711= | Silent (SNP) | VAF 28/175 reads (16%) | catalogued as rs774581670, COSV58743253, COSV58743865; called by muse, mutect2, varscan2
- TCF4 | c.48G>C p.L16= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV61907302; called by muse, mutect2, varscan2
- TMEM145 | c.177C>T p.F59= | Silent (SNP) | VAF 32/170 reads (19%) | catalogued as rs768887283, COSV56628079; called by muse, mutect2, varscan2
- TRIM32 | c.333C>T p.F111= | Silent (SNP) | VAF 15/113 reads (13%) | catalogued as COSV57821993; called by muse, mutect2, varscan2
- UNC45B | c.99G>A p.L33= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as COSV52101410; called by muse, mutect2, varscan2
- URGCP | c.2661C>T p.P887= (on ENST00000453200 / NM_001077663.3; = p.P878= on NM_017920.4) | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as COSV56253487; called by muse, mutect2, varscan2
- VAV1 | c.69G>C p.V23= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as COSV58392410, COSV58392430; called by muse, mutect2, varscan2
- VWA8 | c.2568C>T p.V856= | Silent (SNP) | VAF 35/118 reads (30%) | catalogued as rs1314968943, COSV55706400; called by muse, mutect2, varscan2
- WDR19 | c.1650G>A p.E550= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV56470724; called by muse, mutect2, varscan2
- WDR45 | c.813C>G p.L271= (on ENST00000376372 / NM_001029896.2; = p.L272= on NM_007075.3) | Silent (SNP) | VAF 8/9 reads (89%) | called by mutect2, varscan2
- YEATS2 | c.3165C>G p.L1055= | Silent (SNP) | VAF 5/76 reads (7%) | catalogued as rs1214397356, COSV59373180; called by muse, mutect2
- YEATS2 | c.4116G>A p.L1372= | Silent (SNP) | VAF 47/447 reads (11%) | catalogued as COSV59373192; called by muse, mutect2, varscan2
- ZBTB21 | c.1404G>A p.L468= | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as COSV60406078; called by muse, mutect2, varscan2
- ZNF174 | c.303G>A p.E101= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV51902538, COSV51904594; called by muse, mutect2, varscan2
- ZNF217 | c.2382G>A p.Q794= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV100184894, COSV56603355; called by muse, mutect2, varscan2
- ZNF691 | c.894C>T p.L298= (on ENST00000372502; = p.L267= on NM_015911.3) | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV65289486; called by muse, mutect2, varscan2
- ZNF768 | c.1251C>T p.I417= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs762940397, COSV63324735; called by muse, mutect2, varscan2
- ATP6V0E2 | c.*138G>A | 3'UTR (SNP) | VAF 4/15 reads (27%) | catalogued as COSV101374589; called by muse, mutect2
- BSG | chr19:571558 C>G | 5'Flank (SNP) | VAF 12/52 reads (23%) | catalogued as COSV61078337; called by muse, mutect2, varscan2
- FAM219A | c.*1C>T | 3'UTR (SNP) | VAF 21/28 reads (75%) | catalogued as rs772706250, COSV99896961; called by muse, mutect2, varscan2
- RNF217 | c.1116+2783G>A | Intron (SNP) | VAF 4/15 reads (27%) | catalogued as COSV51577894; called by muse, mutect2, varscan2
- SNORD116-3 | n.6G>A | RNA (SNP) | VAF 16/234 reads (7%) | called by muse, mutect2
- SSPOP | n.7238C>G | RNA (SNP) | VAF 14/70 reads (20%) | catalogued as COSV100022543, COSV100022887; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 13/34 reads (38%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
- TRIM7 | c.618+49G>C | Intron (SNP) | VAF 26/75 reads (35%) | catalogued as COSV99220228; called by muse, mutect2, varscan2
- ZNF207 | c.-135G>A | 5'UTR (SNP) | VAF 40/115 reads (35%) | catalogued as rs1377496492, COSV100340521; called by muse, mutect2, varscan2
